Gene-level copy-number profile of tumor specimen TCGA-24-2260-01A from TCGA case TCGA-24-2260, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 74.2 years (27,112 days).
Specimen TCGA-24-2260-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.eddece9c-b67d-4628-bf3a-5f419574bd6a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-2260-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/db8ebdd4-48a0-4252-9f67-2ace827e5788

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 53; copy number 1: 2,914; copy number 2: 19,740; copy number 3: 19,492; copy number 4: 6,190; copy number 5: 4,538; copy number 6: 4,152; copy number 7: 1,180; copy number 8: 1,063; copy number 9: 76; copy number 10: 262; copy number 11: 110; copy number 12: 24; copy number 13: 7; copy number 15: 1; copy number 18: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-2260-01A-01D-0663-01): tumor purity 0.84, ploidy 3.15, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 53 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:8,314,246–10,612,723, 1 gene (within-gene range 0–1): PTPRD.
- chr9:8,936,079–9,803,784, 4 genes: AL596451.1, RPS26P3, RN7SL5P, AL513422.1.
- chr9:21,321,300–23,849,914, 48 genes (within-gene range 0–2): IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,653 genes in 41 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:159,649,151–160,711,831, 51 genes, copy number 7: AL445528.2, CRPP1, CRP, AL445528.1, DUSP23, FCRL6, SLAMF8, AL590560.2, SNHG28, AL590560.1, VSIG8, AL590560.3, CFAP45, MIR4259, AL590560.5, AL590560.4, TAGLN2, IGSF9, SLAMF9, LINC01133, AL513485.1, KCNJ10, AL513302.1, PIGM, AL121987.1, KCNJ9, IGSF8, ATP1A2, ATP1A4, CASQ1, AL121987.2, PEA15, DCAF8, AL139011.2, AL139011.1, RPSAP18, PEX19, COPA, SUMO1P3, Y_RNA, NCSTN, NHLH1, RNU4-42P, VANGL2, SLAMF6, AL138930.1, CD84, SLAMF1, SETP9, AL121985.1, CD48.
- chr3:88,948,142–110,683,154, 226 genes, copy number 7 (broad region; genes not listed).
- chr3:161,816,909–168,830,599, 52 genes, copy number 7 (within-gene range 6–7): AC131211.1, TOMM22P6, AC128716.1, AC128685.1, LINC01192, RPS6P4, AC079910.1, RNU7-82P, AC084017.1, MIR1263, LINC01323, LINC01324, SI, Y_RNA, LINC02023, SLITRK3, LINC01322, BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1, PPIAP74, ZBBX, LINC01327, SERPINI2, WDR49, PDCD10, HMGN1P8, SERPINI1, AC079822.1, LRRC77P, AC026353.1, MEMO1P3, AC128713.1, HMGN2P26, GOLIM4, AC069243.1, EGFEM1P, AC124893.1, RNU2-20P, MIR551B.
- chr4:44,173,903–44,678,556, 3 genes, copy number 10 (within-gene range 6–10): KCTD8, AC093852.1, YIPF7.
- chr4:73,836,640–75,050,115, 29 genes, copy number 9: CXCL6, PPBPP1, PF4V1, CXCL1, HNRNPA1P55, CXCL1P1, PF4, PPBP, CXCL5, AC097709.1, RN7SL218P, CXCL3, PPBPP2, AC093677.3, AC093677.1, CXCL2, MTHFD2L, AC093677.2, EPGN, EREG, AC021180.1, AREG, AC239584.1, BTC, AC098825.1, HSPE1P23, PARM1, PARM1-AS1, AC110760.1.
- chr4:80,335,730–83,523,348, 54 genes, copy number 7 (within-gene range 2–7): CFAP299, AC105917.1, BMP3, PRKG2, PRKG2-AS1, RNU5A-2P, RASGEF1B, MTCYBP44, COX5BP1, AC021863.1, NPM1P41, HNRNPA3P13, RNU6-499P, BIN2P1, VAMP9P, AC124016.2, HNRNPD, AC124016.1, IGBP1P4, SNORD42, HNRNPDL, ENOPH1, TMEM150C, RPL7AP26, AC067942.1, AC067942.3, AC067942.2, LINC00575, AC067942.4, SCD5, AC073413.1, MIR575, AC073413.2, SEC31A, THAP9-AS1, THAP9, LIN54, Y_RNA, RNU6-615P, COPS4, AC073840.1, PLAC8, AC114781.2, AC114781.3, AC114781.1, COQ2, HPSE, AC114781.5, AC114781.4, HELQ, MRPS18C, ABRAXAS1, SLC25A14P1, RPL30P5.
- chr5:23,013,048–45,895,970, 334 genes, copy number 7–15 (broad region; genes not listed).
- chr6:5,918,564–6,795,402, 18 genes, copy number 7: RN7SL221P, PKMP5, NRN1, F13A1, MIR7853, MIR5683, LY86-AS1, SNAPC5P1, AL162719.1, CNN3P1, LY86, AL031123.2, AL031123.3, AL031123.1, AL031123.4, AL031123.5, AL136361.1, BTF3P7.
- chr6:21,664,185–23,972,941, 17 genes, copy number 7 (within-gene range 6–7): CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2, AL035401.1, AL591416.1, RNU6-1060P, AL139231.1, AL133270.1, AL139093.1, SPTLC1P2, AL032822.1.
- chr6:40,334,775–41,406,561, 31 genes, copy number 7: TDRG1, LINC00951, AL139275.1, LRFN2, RNU6-250P, AL359475.1, AL033380.1, AL583854.1, UNC5CL, OARD1, TSPO2, APOBEC2, NFYA, AL031778.1, ADCY10P1, TREML1, TREM2, TREML2, TREML3P, TREML4, RNA5SP207, TREML5P, AL391903.2, AL391903.3, TREM1, AL391903.1, RNU6-643P, AL672212.1, NCR2, AL136967.1, AL136967.2.
- chr6:41,499,033–41,519,852, 1 gene, copy number 7 (within-gene range 3–7): LINC01276.
- chr6:48,701,491–50,049,929, 26 genes, copy number 8: FO393412.1, AL391538.1, AL022099.1, AL589994.1, AL589994.2, FO393413.1, RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P, RHAG, CRISP2, AL121974.1, AL121950.1, CRISP3, PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112.
- chr7:83,955,777–89,338,528, 50 genes, copy number 9–13 (within-gene range 5–13): SEMA3A, RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972, AC092013.1, SOCS5P1, GRM3, AC005009.1, GRM3-AS1, ELAPOR2, AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4, ABCB1, HNRNPA1P9, RUNDC3B, SLC25A40, DBF4, ADAM22, SRI, SRI-AS1, AC003991.1, STEAP4, AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1, ZNF804B, TEX47.
- chr7:92,131,774–92,245,924, 1 gene, copy number 8 (within-gene range 5–8): AC000120.3.
- chr7:92,198,969–94,077,157, 41 genes, copy number 8: KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2, VPS50, CALCR, MIR653, MIR489, GNGT1, AC002075.2, MIR4652, AC002075.1, NDUFAF4P2, TFPI2, TFPI2-DT, AC002076.1, GNG11, AC006378.1, BET1, BET1-AS1, AC003092.1, AC003092.2.
- chr7:129,611,720–134,579,875, 91 genes, copy number 7–8 (within-gene range 2–8) (broad region; genes not listed).
- chr7:139,315,291–140,673,993, 30 genes, copy number 7 (within-gene range 2–7): RNU6-206P, FMC1, LUC7L2, FMC1-LUC7L2, AC083880.1, RNU6-911P, KLRG2, AC005531.1, CLEC2L, ERHP1, HIPK2, TBXAS1, PARP12, KDM7A, Y_RNA, KDM7A-DT, RNU6-797P, RNU1-58P, AC005377.1, PPP1R2P6, SLC37A3, RNA5SP247, RNA5SP248, RAB19, AC069335.1, MKRN1, DENND2A, Y_RNA, AC006452.1, RN7SL771P.
- chr8:68,330,955–70,790,371, 40 genes, copy number 7 (within-gene range 2–7): C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1, LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, AC120194.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9.
- chr8:70,780,914–70,781,008, 1 gene, copy number 7: Y_RNA.
- chr8:74,320,613–74,518,007, 1 gene, copy number 7 (within-gene range 3–7): GDAP1.
- chr8:74,548,543–77,537,290, 32 genes, copy number 7–12: MIR5681A, MIR5681B, MIR2052HG, PCBP2P2, AC115837.1, MIR2052, AC011632.1, AC026616.1, PI15, AC011632.2, CRISPLD1, AC100782.1, CASC9, LINC02886, HIGD1AP6, PKMP4, HNF4G, AC011029.1, RNU2-54P, AC067773.1, LINC01109, LINC01111, ZFHX4-AS1, AC013509.1, MRPL9P1, ZFHX4, AC011716.1, AC023200.1, MIR3149, PEX2, HIGD1AP18, AC062004.1.
- chr8:89,412,621–96,611,790, 128 genes, copy number 7 (broad region; genes not listed).
- chr8:99,340,305–126,329,538, 370 genes, copy number 8–10 (broad region; genes not listed).
- chr8:129,484,057–134,713,049, 70 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr10:35,638,249–38,783,108, 64 genes, copy number 7 (broad region; genes not listed).
- chr10:52,765,380–53,766,614, 8 genes, copy number 8: MBL2, Y_RNA, AC073174.1, LINC02672, SNRPEP8, AC036101.1, RNA5SP318, AL365496.1.
- chr10:57,304,479–57,982,993, 4 genes, copy number 13: MIR3924, AL731534.1, AC006484.1, MRPS35P3.
- chr14:76,279,173–78,060,278, 59 genes, copy number 11–18: AC016526.3, AC016526.1, ESRRB, AC008050.1, CYCSP1, RPSAP3, AC007376.1, AC007376.2, VASH1, AF111169.3, AF111169.1, VASH1-AS1, ANGEL1, AF111169.4, LRRC74A, RPL22P2, RN7SKP17, AF111169.2, AC007686.4, LINC01629, RN7SL356P, AC007686.1, IRF2BPL, AC007686.3, LINC02288, AC007686.2, LINC02289, AC007686.5, CIPC, AC007375.2, TMEM63C, ZDHHC22, AC007375.3, FAM204DP, AC007375.1, NGB, MIR1260A, POMT2, GSTZ1, TMED8, AC007954.1, SAMD15, NOXRED1, VIPAS39, AHSA1, AF111168.1, ISM2, SPTLC2, RN7SL587P, COX6CP11, ALKBH1, RPL21P10, ZMYND19P1, SLIRP, SNW1, C14orf178, ADCK1, Y_RNA, FXNP1.
- chr14:78,177,803–78,753,878, 6 genes, copy number 10–18: RNA5SP388, RPS26P48, AF099810.1, AC009396.2, AC009396.3, AC009396.1.
- chr14:81,260,656–82,796,221, 15 genes, copy number 7 (within-gene range 4–7): STON2, AL121769.1, DYNLL1P2, LINC02308, SEL1L, LINC01467, EEF1A1P2, LINC02311, AL355838.1, RPL9P6, EIF3LP1, Metazoa_SRP, LINC02301, ENSAP2, AL355095.1.
- chr17:62,035,944–63,005,152, 33 genes, copy number 11: AC018628.2, Y_RNA, Y_RNA, POLRMTP1, AC053481.3, AC053481.4, TBC1D3P2, AC053481.2, AC053481.1, EFCAB3, AC008026.2, RNU7-52P, RPS23P7, METTL2A, TLK2, AC008026.1, AC008026.3, AC080038.2, AC080038.1, MRC2, Y_RNA, AC080038.3, RNU6-446P, AC005821.1, MARCHF10, AC005821.2, MARCHF10-DT, PRELID3BP3, AC005972.3, MIR633, TRMT112P3, AC005972.1, AC005972.2.
- chr17:63,088,162–63,130,947, 2 genes, copy number 11: AC006270.2, AC006270.1.
- chr19:11,368,123–15,339,237, 235 genes, copy number 10–11 (broad region; genes not listed).
- chr19:34,675,717–35,313,807, 42 genes, copy number 7: AC020910.6, ZNF302, AC020910.5, ZNF181, ZNF599, AC020910.3, LINC01801, AC008555.1, AC008555.5, AC008555.2, AC008555.4, AC008555.3, LINC00904, LINC01838, ZNF30-AS1, ZNF30, AC008555.6, ZNF792, GRAMD1A, AC020907.3, AC020907.4, SCN1B, HPN, HPN-AS1, AC020907.1, AC020907.6, FXYD3, MIR6887, LGI4, AC020907.5, FXYD1, AC020907.2, FXYD7, FXYD5, FAM187B, FAM187B2P, LSR, AC002128.2, AC002128.1, USF2, HAMP, MAG.
- chr19:35,641,745–40,348,527, 247 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr20:16,177,933–17,226,146, 18 genes, copy number 7: AL161941.1, PPIAP17, KIF16B, AL049794.1, AL049794.2, RPLP0P1, Y_RNA, AL135938.1, AL034428.1, SNRPB2, OTOR, AL121892.1, U3, RNU6-27P, AL359511.1, RNU1-131P, AL359511.2, AL359511.3.
- chr20:33,731,657–35,950,370, 85 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr20:62,572,671–63,007,035, 26 genes, copy number 10: RPL7P3, BX640514.1, BX640514.2, AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1, LINC00686, NTSR1, AL357033.2, LINC00659, MRGBP, OGFR-AS1, OGFR, COL9A3, TCFL5, DPH3P1, ARF4P2, DIDO1, AL117379.1, GID8, SLC17A9, BHLHE23.
- chr20:63,034,217–63,053,863, 2 genes, copy number 10 (within-gene range 5–10): LINC00029, LINC01056.
- chr22:20,587,496–22,215,270, 109 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,779. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
